Somatic mutation profile of tumor specimen TCGA-44-6775-01A (aliquot TCGA-44-6775-01A-21D-A27T-08) from TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-44-6775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 110338c2-7ea1-490f-b8ea-a2d33c61d5a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6775-10A (Blood Derived Normal), aliquot TCGA-44-6775-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1bb87b4-6856-4c85-801d-7faa0de441fd

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- ADAMTS12 | c.4370G>A p.W1457* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as rs776770546, COSV61276279, COSV61280573; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- ARHGAP21 | c.2883G>T p.M961I | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57611270; called by muse, mutect2, varscan2
- ARHGEF10L | c.2272+2T>G p.X758_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV51440804; called by muse, mutect2, varscan2
- BLM | c.3227A>G p.D1076G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV61927576; called by muse, varscan2
- CDH18 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56936695, COSV56962343; called by muse, mutect2, varscan2
- CPNE4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as COSV101456748; called by muse, mutect2, varscan2
- CSMD3 | c.7704C>A p.Y2568* (on ENST00000297405 / NM_001363185.1; = p.Y2464* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV52134658, COSV52266109; called by mutect2, varscan2
- CTC1 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV59852041; called by muse, mutect2, varscan2
- CWC27 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759472038, COSV66888888; called by muse, mutect2, varscan2
- CXCR2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59282156; called by muse, mutect2, varscan2
- FBXW9 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100790258; called by muse, mutect2, varscan2
- FDPS | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV52742913; called by muse, mutect2, varscan2
- GABRA2 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV62920160; called by muse, mutect2, varscan2
- GABRA4 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51929438; called by muse, mutect2, varscan2
- GLYATL1 | c.563G>A p.R188Q (on ENST00000317391 / NM_001354699.1; = p.R219Q on NM_080661.4) | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs746647261, COSV55607200; called by muse, mutect2
- IBSP | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1262583902, COSV56897395; called by muse, mutect2, varscan2
- ITGAV | c.2124G>T p.Q708H | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.677); catalogued as COSV53719113; called by muse, mutect2, varscan2
- KATNAL1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV66064908; called by muse, mutect2, varscan2
- KLF17 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64857036; called by muse, mutect2, varscan2
- KLHL4 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64143984, COSV64148115; called by muse, mutect2
- KRTAP10-7 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV59113372; called by muse, mutect2, varscan2
- MOCOS | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs778766392, COSV54346907; called by muse, mutect2, varscan2
- MRPS5 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV55535461; called by muse, mutect2, varscan2
- MVP | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420867632, COSV62423622; called by muse, mutect2
- MYT1 | c.2528+2T>C p.X843_splice | Splice Site (SNP) | VAF 144/356 reads (40%) | catalogued as COSV60513900; called by muse, mutect2, varscan2
- NBPF10 | c.11364G>T p.Q3788H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs587642846, COSV61673644; called by mutect2, varscan2
- NCF2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV61634370; called by muse, mutect2
- NF1 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as CD1415163, COSV62222291; called by muse, mutect2, varscan2
- OR6C6 | c.516T>G p.I172M | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100626389; called by muse, mutect2
- PTPRN | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1181242319, COSV55352439; called by muse, mutect2, varscan2
- RB1 | c.1846_1847insT p.K616Ifs*37 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | catalogued as COSV99922623; called by mutect2, pindel, varscan2
- REG3A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs1048512257, COSV59408975, COSV59410712, COSV59411752; called by muse, mutect2, varscan2
- SAGE1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV61018235; called by muse, mutect2, varscan2
- SBF2 | c.4099A>G p.T1367A | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1362020336, COSV56311943; called by muse, mutect2, varscan2
- TEC | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs746395396, COSV63354027; called by muse, mutect2, varscan2
- TNC | c.6098G>T p.R2033L | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60790736; called by muse, mutect2, varscan2
- TTN | c.16311G>C p.K5437N (on ENST00000591111; = p.K4510N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | PolyPhen possibly damaging (0.663); catalogued as COSV60358967; called by muse, mutect2, varscan2
- UGGT2 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65079669; called by muse, mutect2, varscan2
- VPS13C | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV51425770; called by muse, mutect2, varscan2
- VWA3B | c.3311T>C p.V1104A | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs927356360, COSV69034257; called by muse, mutect2, varscan2
- YTHDC1 | c.1867T>A p.Y623N (on ENST00000344157 / NM_001031732.4; = p.Y605N on NM_133370.4) | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60012155; called by muse, mutect2, varscan2
- ZBTB7B | c.746G>A p.G249E (on ENST00000292176; = p.G283E on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV52694899; called by muse, mutect2, varscan2
- BCL9L | c.3185dup p.S1062Rfs*108 | Frame Shift Ins (INS) | VAF 13/95 reads (14%) | called by mutect2, pindel, varscan2
- GABRA5 | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- MET | c.3020_3028+4delinsG p.X1007_splice | Splice Site (DEL) | VAF 12/61 reads (20%) | called by pindel, varscan2*
- RBM25 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2
- AUP1 | c.693C>T p.R231= | Silent (SNP) | VAF 48/302 reads (16%) | catalogued as COSV51214379; called by muse, mutect2, varscan2
- FBXO4 | c.693C>T p.F231= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV55854301; called by muse, mutect2, varscan2
- ICAM1 | c.1359C>G p.G453= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs750997842, COSV53427302; called by muse, mutect2
- KCNA4 | c.1350A>G p.R450= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV60256061; called by muse, mutect2, varscan2
- KRTAP3-2 | c.141C>T p.C47= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV101195993; called by muse, mutect2, varscan2
- PCDHGA9 | c.351C>T p.Y117= | Silent (SNP) | VAF 12/234 reads (5%) | catalogued as rs1561687273, COSV53967367; called by muse, mutect2
- RBM15 | c.720C>T p.L240= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV63924504; called by muse, mutect2, varscan2
- RFC1 | c.3180A>G p.A1060= (on ENST00000381897 / NM_001363496.2; = p.A1059= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/248 reads (21%) | catalogued as COSV56470330; called by muse, mutect2, varscan2
- TAF2 | c.501G>A p.E167= | Silent (SNP) | VAF 18/355 reads (5%) | catalogued as COSV65421267; called by muse, mutect2
- TAF6L | c.759C>A p.S253= | Silent (SNP) | VAF 15/273 reads (5%) | catalogued as COSV99584840; called by muse, mutect2
- TTLL3 | c.1179C>A p.L393= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100047064, COSV59615907; called by muse, mutect2, varscan2
- VBP1 | c.375G>A p.L125= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as COSV99660659; called by muse, mutect2, varscan2
- ZMYM5 | c.1023T>C p.C341= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV61990061; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501251 del AT | 5'Flank (DEL) | VAF 10/51 reads (20%) | catalogued as rs751290649; called by pindel, varscan2
